Somatic mutation profile of tumor specimen MMRF_2047_1_BM_CD138pos (aliquot MMRF_2047_1_BM_CD138pos_T1_KHS5U_L08102) from MMRF case MMRF_2047, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.0 years (24,822 days).
Specimen MMRF_2047_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6718342f-c417-4dbd-89af-350fd72dbff0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2047_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2047_1_PB_Whole_C2_KHS5U_L08103; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8703e6fc-5084-413a-8693-e1790f6b1b39

The open-access MAF lists 177 somatic variants for this specimen: 76 protein-altering or splice-affecting, 26 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, 3'UTR 43, Silent 26, Intron 12, 5'UTR 8, RNA 5, Splice Site 5, 5'Flank 4, Splice Region 4, Frame Shift Del 4, 3'Flank 3, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 32/63 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA2 | c.3637C>T p.R1213W | Missense Mutation (SNP) | VAF 102/173 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs281875238, CM122547, COSV61806839; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ANTXR2 | c.416C>A p.T139N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs1316561811; called by muse, mutect2, varscan2
- ARRDC2 | c.1171-2A>C p.X391_splice | Splice Site (SNP) | VAF 45/156 reads (29%) | catalogued as rs566359277; called by muse, mutect2, varscan2
- C2CD4C | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 117/263 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1384581026; called by muse, mutect2, varscan2
- CD93 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs140540216, COSV55664977; called by muse, mutect2, varscan2
- CFAP58 | c.1706T>C p.L569P | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.395); catalogued as rs773132980; called by muse, mutect2, varscan2
- CKAP4 | c.1498G>A p.V500M | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.134); catalogued as rs199619601; called by muse, mutect2, varscan2
- CYB5RL | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.77); catalogued as rs763991187, COSV55277861; called by muse, mutect2, varscan2
- HERC5 | c.1584A>G p.E528= | Splice Region (SNP) | VAF 22/47 reads (47%) | catalogued as rs1471720730, COSV52043425; called by muse, mutect2, varscan2
- IGHV2-70 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs368500297; called by muse, varscan2
- IGHV2-70 | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.162); catalogued as rs184814603; called by muse, varscan2
- IGLV3-1 | c.112A>G p.S38G | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs368477850; called by muse, varscan2
- IGLV3-1 | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs189772470; called by muse, varscan2
- IGLV3-1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); catalogued as rs61731687; called by muse, varscan2
- IGLV3-1 | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs373605544; called by muse, varscan2
- KCNA1 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as COSV66836958; called by muse, mutect2, varscan2
- KCNK3 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs773957514; called by muse, mutect2
- LAMB2 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 92/152 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs773490060; called by muse, mutect2, varscan2
- LTB | c.163-1G>A p.X55_splice | Splice Site (SNP) | VAF 164/372 reads (44%) | catalogued as rs538858213, COSV53000266; called by muse, mutect2, varscan2
- MAML2 | c.2939C>T p.T980M | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs200584349; called by muse, mutect2, varscan2
- MMD2 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68661094; called by muse, mutect2, varscan2
- PLIN5 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.59); PolyPhen benign (0.048); catalogued as rs747789366, COSV67850361; called by muse, mutect2, varscan2
- PNISR | c.2143C>T p.R715* | Nonsense Mutation (SNP) | VAF 36/77 reads (47%) | catalogued as COSV65080376; called by muse, mutect2, varscan2
- RAB6B | c.72C>T p.V24= | Splice Region (SNP) | VAF 41/787 reads (5%) | catalogued as rs373466732, COSV99557915; called by muse, mutect2
- RHPN2 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs749317155, COSV54283248; called by muse, mutect2
- SLC22A6 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 35/70 reads (50%) | catalogued as COSV100842972; called by muse, mutect2, varscan2
- SLC6A7 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs147922279; called by muse, mutect2, varscan2
- SUCLA2 | c.1106T>G p.V369G (on ENST00000643023; = p.V348G on NM_003850.3) | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs1282208356, COSV66222499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCHH | c.5306G>A p.R1769H | Missense Mutation (SNP) | VAF 79/270 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs371137520; called by muse, mutect2, varscan2
- TMC1 | c.1220del p.N407Mfs*3 | Frame Shift Del (DEL) | VAF 41/90 reads (46%) | catalogued as COSV52767299; called by mutect2, pindel, varscan2
- TMEM163 | c.869G>C p.*290Sext*7 | Nonstop Mutation (SNP) | VAF 12/370 reads (3%) | catalogued as COSV56105222; called by muse, mutect2
- TYRO3 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 81/313 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs752575650; called by muse, mutect2, varscan2
- UNC5B | c.303C>T p.T101= | Splice Region (SNP) | VAF 16/32 reads (50%) | catalogued as rs146776724; called by muse, mutect2, varscan2
- USP6NL | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.262); catalogued as rs953979178; called by muse, mutect2, varscan2
- VHLL | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs373342361; called by muse, mutect2
- WFIKKN2 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs761597315, COSV100260125, COSV60959159; called by muse, mutect2, varscan2
- ZNF594 | c.2410_2412del p.S804del | In Frame Del (DEL) | VAF 120/254 reads (47%) | catalogued as rs1351452775; called by mutect2, pindel, varscan2
- ACTL8 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2
- ADGRL2 | c.2685T>A p.F895L (on ENST00000370717 / NM_001366005.1; = p.F882L on NM_012302.4) | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AMOTL1 | c.998T>A p.F333Y | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- C2orf78 | c.160G>C p.V54L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CD274 | c.682+2T>C p.X228_splice | Splice Site (SNP) | VAF 93/143 reads (65%) | called by muse, mutect2, varscan2
- CDK2AP2 | c.208T>G p.S70A | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CEP57L1 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CLPX | c.358+2T>C p.X120_splice | Splice Site (SNP) | VAF 156/244 reads (64%) | called by muse, varscan2
- CNNM1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- CYBB | c.410A>G p.Y137C | Missense Mutation (SNP) | VAF 41/45 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- GALNT5 | c.2217G>T p.K739N | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); called by muse, mutect2
- H2BC15 | c.232G>C p.A78P | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- HNRNPU | c.2129dup p.N710Kfs*62 (on ENST00000283179; = p.N772Kfs*62 on NM_004501.3) | Frame Shift Ins (INS) | VAF 110/220 reads (50%) | called by mutect2, pindel, varscan2
- LTBP2 | c.2906A>C p.Q969P | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MAP3K3 | c.24C>A p.N8K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MBD6 | c.2012del p.P671Lfs*4 | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | called by mutect2, pindel, varscan2
- MORN3 | c.173A>C p.K58T | Missense Mutation (SNP) | VAF 85/198 reads (43%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRM1 | c.26_42del p.G9Afs*28 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | called by mutect2, pindel, varscan2
- NOL6 | c.558+4A>C | Splice Region (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- PCDH10 | c.2113T>G p.S705A | Missense Mutation (SNP) | VAF 85/177 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKDREJ | c.1185C>A p.S395R | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- PKHD1 | c.4693G>T p.V1565F | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- POLR2A | c.4181A>G p.N1394S | Missense Mutation (SNP) | VAF 16/257 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- PTPRD | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPRR | c.1745G>T p.G582V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RANBP6 | c.2683A>T p.I895L | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RASA1 | c.1388T>C p.I463T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- RIF1 | c.2927A>C p.E976A | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RIN3 | c.1607A>G p.D536G | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RPRD1B | c.825del p.K275Nfs*2 | Frame Shift Del (DEL) | VAF 42/101 reads (42%) | called by pindel, varscan2
- RYR1 | c.9473-2A>G p.X3158_splice | Splice Site (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- RYR2 | c.9926A>C p.K3309T | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- SLC9A3R1 | c.404A>C p.N135T | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK1 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SRF | c.5T>A p.L2* | Nonsense Mutation (SNP) | VAF 41/93 reads (44%) | called by muse, mutect2, varscan2
- TOP1MT | c.1024T>G p.S342A | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRPC5 | c.810C>A p.N270K | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF611 | c.1253_1255del p.R418del | In Frame Del (DEL) | VAF 46/246 reads (19%) | called by pindel, varscan2
- ARHGAP32 | c.5478C>T p.R1826= (on ENST00000310343 / NM_001378025.1; = p.R1477= on NM_014715.4) | Silent (SNP) | VAF 19/244 reads (8%) | called by muse, mutect2
- ARHGEF16 | c.324C>T p.F108= | Silent (SNP) | VAF 48/111 reads (43%) | catalogued as rs749071074, COSV65681366; called by muse, mutect2, varscan2
- ARHGEF2 | c.2661C>T p.L887= (on ENST00000361247 / NM_001162383.2; = p.L859= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 105/159 reads (66%) | catalogued as rs765072859; called by muse, mutect2, varscan2
- BPIFB4 | c.495G>A p.A165= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as rs755057163; called by muse, mutect2, varscan2
- CCDC158 | c.282A>T p.L94= | Silent (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- CXXC5 | c.558G>A p.A186= | Silent (SNP) | VAF 61/141 reads (43%) | catalogued as rs755975384; called by muse, mutect2, varscan2
- DCLK2 | c.930G>T p.G310= | Silent (SNP) | VAF 101/221 reads (46%) | catalogued as COSV56202272; called by muse, mutect2, varscan2
- DNA2 | c.690G>A p.S230= | Silent (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.225T>C p.G75= | Silent (SNP) | VAF 62/131 reads (47%) | called by muse, mutect2, varscan2
- IGHV2-5 | c.12T>G p.L4= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as rs782156438; called by muse, varscan2
- IGKV2-24 | c.333T>C p.Y111= | Silent (SNP) | VAF 50/54 reads (93%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.342A>G p.A114= | Silent (SNP) | VAF 49/111 reads (44%) | catalogued as rs750027938; called by muse, mutect2, varscan2
- LRP4 | c.4611C>T p.D1537= | Silent (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- MAGEL2 | c.615G>A p.P205= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs772217579; called by muse, mutect2, varscan2
- MGAM | c.2928A>G p.E976= | Silent (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- MPP7 | c.219G>A p.A73= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as rs144563385; called by muse, mutect2, varscan2
- MYOF | c.5553G>A p.P1851= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs533854948; called by muse, mutect2, varscan2
- NFKBIB | c.924C>T p.S308= | Silent (SNP) | VAF 96/194 reads (49%) | catalogued as rs758170872; called by muse, mutect2, varscan2
- OCA2 | c.42G>A p.A14= | Silent (SNP) | VAF 13/205 reads (6%) | catalogued as rs762670171, COSV100667885, COSV62343461; called by muse, mutect2
- PDGFA | c.297G>A p.R99= | Silent (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2
- PLA1A | c.1317G>T p.V439= | Silent (SNP) | VAF 233/394 reads (59%) | catalogued as COSV99845707; called by muse, mutect2, varscan2
- PSMD6 | c.747G>T p.V249= | Silent (SNP) | VAF 14/348 reads (4%) | called by muse, mutect2
- SPEG | c.1275G>T p.R425= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- TCF15 | c.435C>T p.G145= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as rs1349567727; called by muse, mutect2
- ZNF502 | c.1269T>A p.I423= | Silent (SNP) | VAF 48/148 reads (32%) | called by muse, mutect2, varscan2
- ZNF536 | c.666G>A p.P222= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as rs1359358418, COSV62827638; called by muse, mutect2, varscan2
- AC005324.2 | c.*1568C>T | 3'UTR (SNP) | VAF 75/172 reads (44%) | catalogued as rs1034764308; called by muse, mutect2, varscan2
- AC021218.1 | n.1152T>A | RNA (SNP) | VAF 75/224 reads (33%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.-240T>C | 5'UTR (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.*7615dup | 3'UTR (INS) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- ASF1A | c.*244A>G | 3'UTR (SNP) | VAF 20/34 reads (59%) | catalogued as rs1208292533; called by muse, mutect2, varscan2
- ATG9B | c.*11C>T | 3'UTR (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- BBS7 | c.*1085A>C | 3'UTR (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021255 C>T | 5'Flank (SNP) | VAF 60/142 reads (42%) | catalogued as rs184586185; called by muse, mutect2, varscan2
- BCL7A | chr12:122021430 del CAGAGATGCGCGA | 5'Flank (DEL) | VAF 40/106 reads (38%) | called by mutect2, pindel, varscan2
- CCDC9B | c.*413T>A | 3'UTR (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- CD177P1 | n.817C>T | RNA (SNP) | VAF 63/232 reads (27%) | catalogued as rs907835645; called by muse, mutect2, varscan2
- CDC73 | c.*590G>C | 3'UTR (SNP) | VAF 38/115 reads (33%) | called by muse, mutect2, varscan2
- CPB2 | c.*204del | 3'UTR (DEL) | VAF 28/52 reads (54%) | catalogued as rs1406172574; called by mutect2, varscan2
- CYFIP1 | chr15:22867290 A>G | 3'Flank (SNP) | VAF 41/140 reads (29%) | called by muse, mutect2, varscan2
- DPP8 | c.*3176C>T | 3'UTR (SNP) | VAF 60/93 reads (65%) | called by muse, mutect2, varscan2
- EGFR | c.*4125A>T | 3'UTR (SNP) | VAF 51/163 reads (31%) | called by muse, mutect2, varscan2
- EIF4A2 | c.30-13T>C | Intron (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- EIF4B | c.*1619_*1660delinsTGGGCTTTTAAAGAGTATTGAAGATTGAAAGGGCT | 3'UTR (DEL) | VAF 15/129 reads (12%) | called by pindel, varscan2*
- ELAPOR2 | c.*1094G>T | 3'UTR (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2
- ETV6 | c.*573A>G | 3'UTR (SNP) | VAF 116/255 reads (45%) | catalogued as rs1204962870; called by muse, mutect2, varscan2
- FANCA | c.2504+22G>A | Intron (SNP) | VAF 56/116 reads (48%) | catalogued as rs186286531; called by muse, mutect2, varscan2
- FIGN | c.*6172T>C | 3'UTR (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- FIGN | c.*2913C>T | 3'UTR (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- FITM2 | c.*3563G>A | 3'UTR (SNP) | VAF 24/58 reads (41%) | catalogued as rs912629415; called by muse, mutect2, varscan2
- GNAL | c.-73G>A | 5'UTR (SNP) | VAF 75/142 reads (53%) | called by muse, mutect2, varscan2
- HCG27 | n.1612C>G | RNA (SNP) | VAF 60/144 reads (42%) | called by muse, mutect2, varscan2
- HNMT | c.*2134C>T | 3'UTR (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- HS6ST1 | c.*810_*811insACTTGTGT | 3'UTR (INS) | VAF 4/36 reads (11%) | catalogued as rs1553454916; called by mutect2, pindel
- IGLL5 | c.-28C>T | 5'UTR (SNP) | VAF 33/76 reads (43%) | catalogued as rs1393780750; called by muse, mutect2, varscan2
- IL7R | c.876+133A>G | Intron (SNP) | VAF 49/97 reads (51%) | called by muse, mutect2, varscan2
- KRAS | c.*3185A>C | 3'UTR (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- LAMC3 | c.*1915G>A | 3'UTR (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- LEF1 | c.1009-15_1009-12del | Intron (DEL) | VAF 22/60 reads (37%) | called by pindel, varscan2
- LINC01098 | n.562C>T | RNA (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- LMOD3 | c.-127T>A | 5'UTR (SNP) | VAF 16/29 reads (55%) | catalogued as rs945534479; called by muse, varscan2
- LRP1B | c.*891A>G | 3'UTR (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- MACROD2 | chr20:13995398 C>T | 5'Flank (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- MECOM | chr3:169084015 T>C | 3'Flank (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- MRPS33 | c.*223G>A | 3'UTR (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2, varscan2
- NOSTRIN | chr2:168802471 C>T | 5'Flank (SNP) | VAF 23/63 reads (37%) | catalogued as rs1338240522; called by muse, mutect2, varscan2
- NREP | c.*1117G>A | 3'UTR (SNP) | VAF 34/459 reads (7%) | catalogued as rs771401766; called by muse, mutect2
- NSMCE3 | c.-78T>G | 5'UTR (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- NTRK3 | c.*5926G>A | 3'UTR (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- PAFAH2 | c.*33C>G | 3'UTR (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- PCDH11Y | c.3129+4104G>A | Intron (SNP) | VAF 16/313 reads (5%) | called by muse, mutect2
- PIK3C3 | c.*2456T>C | 3'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- PIK3C3 | c.*4146A>T | 3'UTR (SNP) | VAF 19/31 reads (61%) | called by muse, mutect2, varscan2
- PPM1A | c.952+397A>T | Intron (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- PPP1CB | c.*2287C>A | 3'UTR (SNP) | VAF 43/101 reads (43%) | catalogued as rs1010167811; called by muse, mutect2, varscan2
- PRDM16 | c.*4038G>A | 3'UTR (SNP) | VAF 21/45 reads (47%) | catalogued as rs1019027889; called by muse, mutect2, varscan2
- PTCD1 | c.*1002C>G | 3'UTR (SNP) | VAF 52/145 reads (36%) | called by muse, mutect2, varscan2
- PTPN7 | c.-52-411G>T | Intron (SNP) | VAF 42/105 reads (40%) | called by muse, mutect2, varscan2
- PTPRQ | c.*927A>C | 3'UTR (SNP) | VAF 35/65 reads (54%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.1102-14T>C | Intron (SNP) | VAF 63/134 reads (47%) | called by muse, mutect2, varscan2
- RC3H1 | c.*3409G>T | 3'UTR (SNP) | VAF 60/181 reads (33%) | called by muse, mutect2, varscan2
- RPE65 | c.*725del | 3'UTR (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- SCAF11 | c.*257G>C | 3'UTR (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.*3373T>G | 3'UTR (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- SLC1A2 | c.*2507C>G | 3'UTR (SNP) | VAF 47/95 reads (49%) | called by muse, mutect2, varscan2
- SPAG4 | c.305-46G>C | Intron (SNP) | VAF 45/112 reads (40%) | called by muse, mutect2, varscan2
- STAG3L4 | n.310T>G | RNA (SNP) | VAF 150/622 reads (24%) | called by muse, mutect2, varscan2
- TBC1D4 | c.-131T>C | 5'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, varscan2
- TBC1D4 | c.-192T>C | 5'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, varscan2
- TDRP | c.*1117del | 3'UTR (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- TECRL | chr4:64276204 A>G | 3'Flank (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- TIA1 | c.277+51T>G | Intron (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- TMCC1 | c.*3319T>G | 3'UTR (SNP) | VAF 47/81 reads (58%) | called by muse, mutect2, varscan2
- TNFRSF11A | c.*2550T>C | 3'UTR (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- TNS4 | c.*1019T>G | 3'UTR (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- TTN | c.38557+56T>C | Intron (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- TUSC1 | c.*1155A>T | 3'UTR (SNP) | VAF 112/188 reads (60%) | called by muse, mutect2, varscan2
- USP38 | c.-374C>T | 5'UTR (SNP) | VAF 112/195 reads (57%) | called by muse, mutect2, varscan2
- VGLL3 | c.*901G>A | 3'UTR (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- WNT16 | c.*1272_*1276del | 3'UTR (DEL) | VAF 31/91 reads (34%) | catalogued as rs1369238470; called by mutect2, pindel, varscan2
- ZSWIM4 | c.1180+1686A>G | Intron (SNP) | VAF 36/131 reads (27%) | catalogued as rs781744042; called by muse, mutect2, varscan2
